Somatic mutation profile of tumor specimen TCGA-42-2593-01A (aliquot TCGA-42-2593-01A-01D-1764-09) from TCGA case TCGA-42-2593, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.0 years (24,823 days).
Specimen TCGA-42-2593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 617fb2e6-66e8-4450-856c-975b9d94caee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2593-10A (Blood Derived Normal), aliquot TCGA-42-2593-10A-01D-1764-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de1058f9-2aeb-4757-ae4a-4aea97679750

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEGS1 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs768180196, COSV100083412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.815T>G p.V272G | Missense Mutation (SNP) | VAF 72/92 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660333, CM942122, COSV52701102, COSV52773741, COSV52787833, COSV53259929; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADAC | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233379; called by muse, mutect2, varscan2
- ADAM33 | c.177+1G>A p.X59_splice | Splice Site (SNP) | VAF 50/225 reads (22%) | catalogued as rs1185238560, COSV100597975; called by muse, mutect2, varscan2
- ADGRB3 | c.4388C>G p.P1463R | Missense Mutation (SNP) | VAF 88/463 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99486074; called by muse, mutect2, varscan2
- ADGRE1 | c.2278A>G p.T760A | Missense Mutation (SNP) | VAF 149/395 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99165502; called by muse, mutect2, varscan2
- ATAT1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99457825; called by muse, mutect2, varscan2
- ATP11B | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 66/308 reads (21%) | catalogued as COSV100017942; called by muse, mutect2, varscan2
- CD180 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV56517788, COSV99842304; called by muse, mutect2, varscan2
- CLCN6 | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755723649, COSV100412056; called by muse, mutect2, varscan2
- CLDN18 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 144/753 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV59302948; called by muse, mutect2, varscan2
- CPVL | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 166/596 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV99606127; called by muse, mutect2, varscan2
- CYP2B6 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV100137636; called by muse, mutect2, varscan2
- DDX18 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99604648; called by muse, mutect2, varscan2
- ETV3L | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101485603, COSV71901038; called by muse, mutect2, varscan2
- FGFR1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs747842199, CM149875, COSV58339283; called by muse, mutect2, varscan2
- FKBP2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs896249907, COSV100501811, COSV58587929; called by muse, mutect2, varscan2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 66/274 reads (24%) | catalogued as rs34148688; called by mutect2, varscan2
- HAUS6 | c.1879G>C p.V627L | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV100997869; called by muse, mutect2, varscan2
- HEATR4 | c.2765T>C p.L922S | Missense Mutation (SNP) | VAF 156/465 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100408060; called by muse, mutect2, varscan2
- HIVEP3 | c.3803T>C p.L1268P | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1410586248, COSV99913273; called by muse, mutect2, varscan2
- NPAS3 | c.1762G>A p.E588K (on ENST00000356141 / NM_001164749.2; = p.E556K on NM_022123.3) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs769133720, COSV60831240, COSV60833051; called by muse, mutect2, varscan2
- PFKFB2 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 69/331 reads (21%) | PolyPhen benign (0.05); catalogued as COSV100892028; called by muse, mutect2, varscan2
- PTK7 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 89/521 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs376445655; called by muse, mutect2, varscan2
- RSF1 | c.3266G>A p.R1089Q | Missense Mutation (SNP) | VAF 206/915 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776963058, COSV100407495; called by muse, mutect2, varscan2
- RTKN | c.470A>G p.E157G (on ENST00000272430 / NM_001015055.2; = p.E144G on NM_033046.2) | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99269773; called by muse, varscan2
- SIGLEC7 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99978826; called by muse, mutect2, varscan2
- SIX4 | c.2035C>G p.P679A | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV99382382; called by muse, mutect2, varscan2
- SLC9A2 | c.2314C>G p.Q772E | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99296488; called by muse, mutect2, varscan2
- SP100 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749706905, COSV51001246; called by muse, mutect2, varscan2
- TERT | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 117/620 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV57200256; called by muse, mutect2, varscan2
- ZNF596 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100261698; called by muse, mutect2, varscan2
- ABCC11 | c.2755del p.L919Ffs*2 | Frame Shift Del (DEL) | VAF 50/121 reads (41%) | called by mutect2, pindel, varscan2
- CAMKK1 | c.51A>G p.V17= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV99340422; called by muse, mutect2, varscan2
- DIDO1 | c.2031C>T p.S677= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV99826423; called by muse, mutect2, varscan2
- FECH | c.495C>T p.Y165= | Silent (SNP) | VAF 232/524 reads (44%) | catalogued as rs752506843, COSV100023685; called by muse, mutect2, varscan2
- GABRA3 | c.1311C>T p.T437= | Silent (SNP) | VAF 16/519 reads (3%) | catalogued as COSV100943046; called by muse, mutect2
- KIR2DL4 | c.957G>A p.A319= (on ENST00000396284; = p.A245= on NM_001080770.2) | Silent (SNP) | VAF 66/346 reads (19%) | catalogued as rs187597433; called by muse, mutect2
- LPO | c.1899C>T p.G633= | Silent (SNP) | VAF 49/243 reads (20%) | catalogued as rs367661436; called by muse, mutect2, varscan2
- MCHR2 | c.576C>T p.D192= | Silent (SNP) | VAF 374/619 reads (60%) | catalogued as rs201955415, COSV56001330; called by muse, mutect2, varscan2
- MCM2 | c.187C>T p.L63= | Silent (SNP) | VAF 89/439 reads (20%) | catalogued as COSV99412911, COSV99413279; called by muse, mutect2, varscan2
- MYCBP2 | c.10893C>T p.S3631= (on ENST00000357337; = p.S3669= on NM_015057.5) | Silent (SNP) | VAF 153/551 reads (28%) | catalogued as rs141958299; called by muse, mutect2, varscan2
- PCDHGA7 | c.1947C>T p.H649= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54057740; called by muse, mutect2, varscan2
- PHF20 | c.888C>T p.V296= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV100180499; called by muse, mutect2, varscan2
- PLA2G12A | c.51C>T p.A17= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as rs988151748, COSV54669357, COSV99697362; called by muse, mutect2
- SESN2 | c.1386G>A p.A462= | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as rs763448717, COSV99455549; called by muse, mutect2, varscan2
- SVIL | c.4551A>G p.Q1517= (on ENST00000355867 / NM_021738.3; = p.Q1091= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/305 reads (31%) | catalogued as rs377454947; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048367 G>A | 5'Flank (SNP) | VAF 40/147 reads (27%) | called by muse, mutect2, varscan2
